Surgical pathology report (de-identified scan), TCGA case TCGA-ET-A3BQ, project TCGA-THCA (Thyroid Carcinoma), tissue source site Johns Hopkins, specimen TCGA-ET-A3BQ-01B (Primary Tumor).

	lw	10/15/11

SPECIMEN TAKEN

FINAL DIAGNOSIS -----

1. THYROID (TOTAL THYROIDECTOMY):

SPECIMEN TYPE:

Total thyroidectomy.

TUMOR SITE:

Right lobe.

HISTOLOGIC TYPE:

Papillary carcinoma.

TUMOR SIZE (LARGEST NODULE):

Greatest dimension: 3.0 cm.

FOCALITY:

Unifocal.

LYMPH NODES (ALL PARTS):

All two (2) lymph nodes are negative for tumor.

EXTENT OF INVASION (STAGING):

PRIMARY TUMOR:

pT2: Tumor >2.0 cm, but <4.0 cm, limited to thyroid.

REGIONAL LYMPH NODES:

pN0: No regional lymph node metastasis.

DISTANT METASTASIS:

pMx: Cannot be assessed.

MARGINS:

Margins are uninvolved.

Distance of invasive carcinoma from nearest margin (inked anterior surface) is <1.0 mm.

VENOUS/LYMPHATIC INVASION:

Absent.

ADDITIONAL PATHOLOGIC FINDINGS:

Mild lymphocytic thyroiditis; Single adenomatoid nodule in the right lobe (0.3 cm).

ICD-O-3

carcinoma, papillary, thyroid

8260/3

Site: thyroid, nos C73.9

lw
10/15/11

Source: NCI Genomic Data Commons file 8b262478-0962-4b83-a9a3-998d3eb862e8 (TCGA-ET-A3BQ.D00A2399-3F56-472B-9382-93651D6EFB0E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).